CCDI case PBCKRV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4e414322-ccef-4bc9-836b-ee4cf08f379c

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Oligodendroglioma, NOS: ICD-O-3 morphology code: 9450/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.5 years (3,830 days).

Biospecimens (3 samples)
- Sample 0DU4UQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU4V4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU4VK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
